Gene-level copy-number profile of tumor specimen ALCH-B2DO-TTP1-A from ALCHEMIST case ALCH-B2DO, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 58.5 years (21,360 days).
Specimen ALCH-B2DO-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 71ac3372-7299-4937-84e2-825e54ae384e.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2DO-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,222 have no estimate.
https://portal.gdc.cancer.gov/files/f4a0932a-29ea-4b0d-9b2a-7dd44c9e35f5

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 10; copy number 1: 387; copy number 2: 54,321; copy number 3: 3,478; copy number 4: 155; copy number 5: 2; copy number 7: 47; copy number 29: 1.

Homozygous deletions (total copy number 0; autosomes only): 10 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:158,131,983–158,149,810, 1 gene: LINC01704.
- chr16:649,311–667,833, 2 genes (within-gene range 0–1): WDR90, AL022341.2.
- chr16:89,919,165–89,968,060, 4 genes (within-gene range 0–2): AC092143.1, AC092143.2, TUBB3, DEF8.
- chr19:5,782,960–5,791,225, 3 genes: PRR22, AC011499.1, DUS3L.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 50 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:104,687,241–107,824,317, 49 genes, copy number 5–7: AL356967.1, HACE1, RNU6-897P, AL357315.1, AL357315.2, LIN28B-AS1, LIN28B, RNU6-1106P, BVES, BVES-AS1, POPDC3, PREP, AL133406.2, AL133406.1, RPL35P3, LINC02836, Z97206.1, RN7SKP211, PRDM1, ATG5, AL022067.1, U4, RN7SL47P, RNU6-344P, AL356859.1, CRYBG1, Y_RNA, RNA5SP211, AL109920.1, Y_RNA, RTN4IP1, RNU6-527P, QRSL1, RPL21P65, LINC02526, LINC02532, RNU6-117P, MIR587, CD24, MTRES1, BEND3, RNU6-1299P, PDSS2, AL591516.1, RPS24P12, SOBP, AL121957.1, AL096816.1, SCML4.
- chr21:43,414,483–43,427,131, 1 gene, copy number 29: SIK1.

Autosomal genes at a single copy (total copy number 1): 387. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
